Somatic mutation profile of tumor specimen TCGA-4V-A9QL-01A (aliquot TCGA-4V-A9QL-01A-11D-A423-09) from TCGA case TCGA-4V-A9QL, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 58.1 years (21,216 days).
Specimen TCGA-4V-A9QL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fd38b93-66be-4f54-83ca-91f493d6e43e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4V-A9QL-11A (Solid Tissue Normal), aliquot TCGA-4V-A9QL-11A-11D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14aebc2d-26bf-4950-8919-c5622a9a63d6

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MORC2 | c.1956G>C p.K652N (on ENST00000397641 / NM_001303256.3; = p.K590N on NM_014941.3) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as rs763542037; ClinVar: uncertain significance; called by muse, varscan2
- STK33 | c.921G>A p.W307* | Nonsense Mutation (SNP) | VAF 9/243 reads (4%) | catalogued as rs1319678294; called by muse, mutect2
- COL14A1 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPA6 | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRG2 | c.2421G>C p.V807= (on ENST00000379869 / NM_001079858.3; = p.V804= on NM_005756.4) | Silent (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- HCN4 | c.1770G>T p.V590= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
